Somatic mutation profile of tumor specimen TCGA-EX-A8YF-01A (aliquot TCGA-EX-A8YF-01A-11D-A37N-09) from TCGA case TCGA-EX-A8YF, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 44.5 years (16,258 days).
Specimen TCGA-EX-A8YF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36204e9c-dae9-4ab0-99cc-430c1d8bd471.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EX-A8YF-10A (Blood Derived Normal), aliquot TCGA-EX-A8YF-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2d2418d-2bce-4c90-b532-7cbaf451ea1e

The open-access MAF lists 49 somatic variants for this specimen: 35 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 12, Nonsense Mutation 6, Splice Region 1, RNA 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOX2 | c.1635G>T p.V545= | Splice Region (SNP) | VAF 7/36 reads (19%) | catalogued as rs754110680, COSV100250338; called by muse, mutect2, varscan2
- ACTN2 | c.1278G>C p.Q426H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.383); catalogued as COSV100857130, COSV63977545; called by muse, mutect2, varscan2
- ANAPC2 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100119282, COSV99047956; called by muse, mutect2, varscan2
- BCL2L11 | c.553C>T p.R185* (on ENST00000393256 / NM_138621.5; = p.R125* on NM_006538.5) | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV58031349; called by muse, mutect2, varscan2
- CD53 | c.646A>C p.T216P | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV99602438; called by muse, mutect2, varscan2
- CHRNB2 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs79646221, COSV100872623; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNMT3B | c.1811C>T p.S604F | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99145580; called by muse, mutect2, varscan2
- FAT1 | c.11659C>T p.Q3887* | Nonsense Mutation (SNP) | VAF 11/20 reads (55%) | catalogued as rs777379412, COSV101499721; called by muse, mutect2, varscan2
- GRIN2A | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as CM138218, COSV100411494, COSV58029019; called by muse, mutect2, varscan2
- HINFP | c.25C>G p.R9G | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100640907; called by muse, mutect2, varscan2
- HSF1 | c.1051G>A p.A351T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs377258216; called by mutect2, varscan2
- ITIH6 | c.3106G>A p.D1036N | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV99514211; called by muse, mutect2, varscan2
- KIFAP3 | c.1253C>G p.S418* | Nonsense Mutation (SNP) | VAF 21/47 reads (45%) | catalogued as rs1459836238, COSV100847197; called by muse, mutect2, varscan2
- LRP2 | c.11293C>T p.R3765* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as COSV55548258; called by muse, mutect2, varscan2
- LRP5 | c.3932T>C p.V1311A | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV99592867; called by muse, mutect2, varscan2
- MMP11 | c.913C>T p.R305* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as rs1267449886, COSV99303480; called by muse, mutect2, varscan2
- MYH7 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100806904; called by muse, mutect2, varscan2
- NONO | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV99339230; called by muse, mutect2, varscan2
- OR1L3 | c.825C>G p.I275M | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV100506346; called by mutect2, varscan2
- OR4A5 | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV60524276; called by muse, mutect2
- PASK | c.3380G>A p.R1127H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370099607; called by muse, mutect2, varscan2
- PCDHB14 | c.2090T>G p.V697G | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV99506409; called by muse, mutect2
- PCDHB15 | c.425T>C p.I142T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99179334; called by muse, mutect2, varscan2
- PTK7 | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1290527344, COSV57847769; called by muse, mutect2, varscan2
- RHCE | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV99604560; called by muse, mutect2, varscan2
- ROCK2 | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as COSV99838057; called by muse, mutect2, varscan2
- RPRD1A | c.634C>T p.L212F | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100036488; called by muse, mutect2, varscan2
- SCN7A | c.4064A>G p.H1355R | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.268); catalogued as COSV101313400; called by mutect2, varscan2
- SMCO3 | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV99660969; called by muse, mutect2, varscan2
- TNRC6A | c.2121T>G p.I707M | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.804); catalogued as COSV100170663; called by muse, mutect2, varscan2
- TRIB3 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753115173, COSV53930777; called by muse, mutect2, varscan2
- UBE2D3 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.91); catalogued as COSV100415041; called by muse, mutect2, varscan2
- ZNF85 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as rs533810051, COSV100060228; called by muse, mutect2, varscan2
- DBF4B | c.779A>G p.D260G | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2
- DUOX2 | c.2718dup p.M907Yfs*26 | Frame Shift Ins (INS) | VAF 13/60 reads (22%) | called by mutect2, pindel, varscan2
- C1QTNF5 | c.663C>T p.I221= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs745716719, COSV100264989; called by muse, mutect2, varscan2
- GRM8 | c.1419C>T p.I473= | Silent (SNP) | VAF 34/77 reads (44%) | catalogued as COSV58835511, COSV58857535; called by muse, mutect2, varscan2
- IGF1 | c.192C>T p.F64= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs760590942, COSV61031820; called by muse, mutect2, varscan2
- KRT8 | c.225C>T p.P75= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs762269088, COSV99510389; called by muse, mutect2, varscan2
- MDN1 | c.12183G>A p.R4061= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV101021971; called by muse, mutect2, varscan2
- MUC5B | c.4281C>T p.C1427= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs767108519, COSV101500996; called by muse, mutect2, varscan2
- NDUFB11 | c.78C>T p.R26= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV99333411; called by muse, mutect2, varscan2
- NMT1 | c.1071G>A p.L357= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99365128; called by muse, mutect2, varscan2
- PCDHB3 | c.2034G>A p.P678= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs1554272644, COSV99167241; called by muse, mutect2, varscan2
- PTGIS | c.1479C>A p.P493= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs756114643, COSV99721045, COSV99721412; called by muse, mutect2, varscan2
- SERBP1 | c.1056G>A p.T352= (on ENST00000370995 / NM_001018067.2; = p.T331= on NM_015640.4) | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs1174309777, COSV100769194; called by mutect2, varscan2
- USP36 | c.1431G>A p.K477= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100361950; called by muse, mutect2, varscan2
- DCHS2 | n.2513C>T | RNA (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100253636; called by muse, mutect2, varscan2
- DDX41 | c.*739G>A | 3'UTR (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100394595; called by muse, mutect2, varscan2
